CCDI case PBCBKE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/085a453a-cc50-4ecc-80a2-859ffcaa215b

Demographics
Sex at birth: female.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.9 years (3,986 days).

Biospecimens (3 samples)
- Sample 0DN9EH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN9EP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DN9EX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
